Gene-level copy-number profile of tumor specimen C3L-04083-02 (profiled together with C3L-04083-03) from CPTAC case C3L-04083, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.0 years (21,910 days).
Specimen C3L-04083-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7d0ab7ac-b9d2-4553-9b94-778c4362db09.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04083-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/e7f990cd-b77d-4f09-a5ed-05cf6e28ce46

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 3,546; copy number 3: 823; copy number 4: 50,562; copy number 5: 171; copy number 6: 3,048; copy number 7: 26; copy number 8: 10; copy number 9: 104; copy number 10: 1; copy number 13: 17; copy number 17: 3; copy number 60: 3; copy number 61: 1; copy number 62: 5; copy number 65: 5; copy number 68: 2; copy number 72: 4; copy number 80: 3; copy number 83: 3; copy number 84: 30; copy number 85: 1; copy number 88: 9; copy number 90: 5; copy number 111: 3; copy number 132: 10; copy number 173: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 217 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:31,509,755–33,736,479, 47 genes, copy number 84–173: ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3, KIAA1549L, AL137161.1, AL133399.1, AL049629.1, C11orf91, AL049629.2, CD59.
- chr12:57,253,762–57,547,224, 15 genes, copy number 13 (within-gene range 2–13): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2.
- chr12:57,674,665–57,797,554, 13 genes, copy number 61–132 (within-gene range 5–132): RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3.
- chr12:57,906,039–57,959,148, 1 gene, copy number 72 (within-gene range 2–72): ATP23.
- chr12:57,967,058–58,105,935, 6 genes, copy number 72–111: AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:66,251,745–67,069,162, 7 genes, copy number 60–85 (within-gene range 2–85): AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:68,473,741–68,971,570, 21 genes, copy number 10–90 (within-gene range 4–90): AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5.
- chr19:186,373–1,812,276, 104 genes, copy number 9 (broad region; genes not listed).
- chr21:9,068,361–9,129,752, 3 genes, copy number 17: TEKT4P2, SOWAHCP2, CR392039.2.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
